Gene-level copy-number profile of tumor specimen TCGA-XK-AAJA-01A from TCGA case TCGA-XK-AAJA, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.3 years (22,771 days).
Specimen TCGA-XK-AAJA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.a899328a-df34-4ee5-9a1b-fde273ba16dc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XK-AAJA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b633828e-ee4b-44db-a7f5-1fc6502cf04c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 215; copy number 1: 6,252; copy number 2: 53,336; copy number 3: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XK-AAJA-01A-11D-A41J-01): tumor purity 0.74, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:166,165,911–166,580,705, 6 genes (within-gene range 0–2): AL596087.2, AL596087.1, AL583804.1, FMO7P, LINC01675, FMO8P.
- chr2:127,141,976–127,143,793, 1 gene: AC110926.1.
- chr3:78,038,705–78,525,485, 6 genes: LINC02077, AC117462.1, RN7SL647P, RN7SKP61, AC108752.1, MRPS17P3.
- chr3:79,411,714–79,507,969, 2 genes: AC117461.1, MIR3923.
- chr3:87,792,492–88,168,729, 7 genes (within-gene range 0–1): HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38.
- chr4:60,750,575–61,153,962, 4 genes: LINC02496, AC105420.1, MIR548AG1, LINC02271.
- chr4:61,211,652–61,212,203, 1 gene: RPL17P19.
- chr6:103,002,514–103,003,897, 1 gene: Z98755.1.
- chr8:105,662,352–105,685,765, 2 genes: AC103853.1, AC103853.2.
- chr18:60,125,033–60,902,726, 14 genes: AC090771.2, RPS3AP49, RNU4-17P, AC090771.1, AC090621.1, AC091576.1, MC4R, AC010928.2, MRPS5P4, AC010928.3, AC010928.1, AC113137.1, CTBP2P3, HMGN1P31.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,036. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
